Somatic mutation profile of tumor specimen MBCProject_3717_T3_WES (aliquot MBCProject_3717_T3_WES_1) from CMI case MBCProject_3717, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Ductal carcinoma in situ, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 44.3 years (16,182 days).
Specimen MBCProject_3717_T3_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Axilla; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3118cc4e-b8fd-4131-8bed-354682115e2a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_3717_SALIVA (Saliva), aliquot MBCProject_3717_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f1df436-8b5b-459a-b4e0-aa2c1e62ddeb

The open-access MAF lists 402 somatic variants for this specimen: 264 protein-altering or splice-affecting, 91 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 226, Silent 91, Nonsense Mutation 26, Intron 22, 5'UTR 10, 3'UTR 7, Splice Region 7, RNA 3, 5'Flank 3, 3'Flank 2, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC25A19 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs759157320, COSV57468752; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 29/57 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.3205C>G p.L1069V (on ENST00000272895 / NM_173076.3; = p.L751V on NM_015657.3) | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV55975703; called by muse, mutect2, varscan2
- ABCB5 | c.2162G>C p.G721A (on ENST00000404938 / NM_001163941.2; = p.G276A on NM_178559.6) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as COSV51718568; called by muse, mutect2, varscan2
- ABCG2 | c.1333G>A p.V445M | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.879); catalogued as rs765641486, COSV52943147; called by mutect2, varscan2
- ACRV1 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV100223636; called by muse, mutect2, varscan2
- ADAM22 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs370626885, COSV55973954; called by muse, mutect2, varscan2
- ADAMTS16 | c.1769C>T p.S590L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1183795725, COSV56997874; called by muse, mutect2
- APRT | c.174C>G p.I58M | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs1445678588, COSV51939031; called by muse, mutect2, varscan2
- ARID1B | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious, low confidence (0); catalogued as rs1325414473; called by muse, mutect2, varscan2
- BCL7A | c.19C>G p.R7G | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as rs756484707, COSV55847310, COSV55849716, COSV55850251; called by muse, mutect2, varscan2
- BRWD1 | c.3482C>G p.S1161* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100312995, COSV60898610; called by muse, mutect2, varscan2
- C11orf16 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV100393725; called by muse, mutect2, varscan2
- CACNA1I | c.4957G>A p.E1653K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1482010114; called by muse, mutect2
- CACTIN | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as COSV50267684; called by muse, varscan2
- CCDC93 | c.1184A>G p.N395S | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV60122956; called by muse, mutect2, varscan2
- CD27 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.938); catalogued as rs763617266, COSV56949851; called by mutect2, varscan2
- CD5 | c.1301C>T p.T434M | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as rs145264378; called by mutect2, varscan2
- CEP104 | c.1313_1317+2del p.X438_splice | Splice Site (DEL) | VAF 4/26 reads (15%) | catalogued as rs758071446; called by mutect2, pindel*
- CHD7 | c.8448G>C p.L2816F | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV71111945; called by muse, mutect2
- CIAO3 | c.492G>C p.E164D | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773434569; called by muse, mutect2
- CNGA4 | c.898G>C p.E300Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV101171818; called by muse, mutect2, varscan2
- COBL | c.2957G>C p.R986P | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs368670111; called by muse, mutect2, varscan2
- CSMD3 | c.7162C>T p.H2388Y (on ENST00000297405 / NM_001363185.1; = p.H2284Y on NM_052900.3) | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.024); catalogued as COSV52264776, COSV52291109; called by muse, mutect2
- CYP11B1 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 157/176 reads (89%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV52827694; called by muse, mutect2, varscan2
- DDR1 | c.2347G>T p.A783S (on ENST00000324771; = p.A746S on NM_001954.4) | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV104411287; called by muse, mutect2, varscan2
- DIXDC1 | c.1571G>A p.R524H (on ENST00000440460 / NM_001037954.4; = p.R313H on NM_033425.4) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs782795755; called by muse, mutect2, varscan2
- DNAI3 | c.1192G>C p.D398H | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs776292330; called by muse, mutect2, varscan2
- DNAJC24 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | catalogued as COSV101231528; called by muse, mutect2, varscan2
- DRC7 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs563865067, COSV61053397; called by muse, mutect2, varscan2
- EGFR | c.2227G>A p.A743T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759256622, COSV51795632; called by mutect2, varscan2
- EIF2B2 | c.46G>C p.E16Q | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.134); catalogued as rs776788187; called by muse, mutect2, varscan2
- EIF3B | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1328238724; called by muse, mutect2, varscan2
- EME2 | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs150023204; called by muse, mutect2, varscan2
- EMP2 | c.176C>G p.S59C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV63995820; called by muse, varscan2
- F8 | c.5317G>A p.E1773K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); catalogued as CM111357, COSV64274516; called by muse, mutect2, varscan2
- FAM71B | c.1142C>G p.T381R | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.157); catalogued as COSV57228795; called by muse, mutect2, varscan2
- FBXW10 | c.2911C>T p.R971C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs759030475, COSV57059970; called by muse, mutect2, varscan2
- FOS | c.755C>T p.S252L | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV57840246; called by muse, mutect2, varscan2
- FPR2 | c.933G>C p.E311D | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.12); catalogued as rs1284602219, COSV104412244; called by muse, mutect2, varscan2
- FRMD4A | c.655C>T p.H219Y | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1442685617; called by muse, mutect2, varscan2
- GCM1 | c.569G>C p.R190T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs559949597, COSV52521430; called by muse, mutect2, varscan2
- GTF3C5 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as COSV59601425; called by muse, mutect2, varscan2
- H3C2 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.676); catalogued as COSV52518637, COSV52519594, COSV99451261; called by muse, mutect2, varscan2
- HDAC9 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs201873826; called by muse, mutect2, varscan2
- HLA-C | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.101); catalogued as rs11547351, COSV100880030, COSV100880740, COSV100880756; called by muse, mutect2, varscan2
- HSPA6 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as rs761626559; called by muse, mutect2, varscan2
- ILK | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.066); catalogued as rs1300901328, COSV54989401, COSV54993088; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1579G>C p.V527L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.183); catalogued as COSV58019011; called by muse, mutect2, varscan2
- KCNH5 | c.2620C>T p.R874C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs754436628, COSV59753363; called by muse, mutect2, varscan2
- KDR | c.2518C>T p.L840F | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99819063; called by muse, mutect2, varscan2
- KIF2B | c.1729C>T p.Q577* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as rs1307780614, COSV52135303; called by muse, mutect2, varscan2
- KIN | c.1086G>C p.E362D | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as COSV65430839; called by muse, mutect2, varscan2
- KLC2 | c.1414G>C p.E472Q | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1565175556; called by muse, mutect2, varscan2
- LRRTM4 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.134); catalogued as rs878988220, COSV101297423, COSV69138902, COSV69140714; called by muse, mutect2, varscan2
- LRTM2 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.556); catalogued as rs766798117, COSV54566528; called by mutect2, varscan2
- MLPH | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as rs11539365; called by muse, mutect2, varscan2
- MMP12 | c.965C>A p.S322Y | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV58260230; called by muse, mutect2, varscan2
- MTG2 | c.946G>C p.E316Q | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.3); catalogued as COSV100895189; called by muse, mutect2, varscan2
- NBPF3 | c.478C>T p.R160* | Nonsense Mutation (SNP) | VAF 14/47 reads (30%) | catalogued as rs781276910; called by muse, mutect2, varscan2
- NLRP1 | c.3804G>A p.M1268I | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV52560941, COSV52566767; called by muse, mutect2, varscan2
- NOVA1 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.953); catalogued as COSV99949050; called by muse, mutect2, varscan2
- NRBP1 | c.566+5G>C | Splice Region (SNP) | VAF 6/40 reads (15%) | catalogued as rs1023250846; called by muse, mutect2, varscan2
- OPLAH | c.2544C>G p.F848L | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs781916565, COSV101470764; called by muse, mutect2
- OR51I1 | c.876C>G p.I292M | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as rs758039849; called by mutect2, varscan2
- PAF1 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs147378857; called by muse, mutect2, varscan2
- PAX8 | c.7C>T p.H3Y | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.682); catalogued as COSV54511121; called by muse, mutect2, varscan2
- PCDHA4 | c.800C>T p.S267L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.45); catalogued as COSV100793349, COSV100793444; called by muse, mutect2, varscan2
- PCDHB3 | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV50565481; called by muse, mutect2, varscan2
- PCNX3 | c.3476C>T p.T1159M | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs185911788, COSV99053540; called by mutect2, varscan2
- PDS5A | c.3334G>A p.E1112K | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.096); catalogued as COSV57826067; called by muse, mutect2, varscan2
- PHYHIPL | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV65848183; called by muse, mutect2, varscan2
- PON3 | c.531C>G p.F177L | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55702258; called by muse, mutect2, varscan2
- POP1 | c.2269G>A p.D757N | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs750208983; called by muse, mutect2, varscan2
- PPP1R16A | c.797G>A p.W266* | Nonsense Mutation (SNP) | VAF 8/118 reads (7%) | catalogued as COSV52952330; called by muse, mutect2
- PSG11 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as rs374240794, COSV60453681, COSV60457534; called by muse, mutect2, varscan2
- PSMB10 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs956621329, COSV99863154; called by muse, varscan2
- PTCH2 | c.3355G>A p.E1119K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs766636037; called by muse, mutect2, varscan2
- RPA4 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV61261970; called by muse, mutect2, varscan2
- SETD2 | c.3002C>T p.S1001F | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV57431095; called by muse, mutect2, varscan2
- SEZ6L | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.063); catalogued as rs1219092259; called by muse, mutect2
- SHTN1 | c.835G>C p.E279Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.938); catalogued as COSV53382065; called by muse, mutect2, varscan2
- SLC25A47 | c.108C>G p.I36M | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV64162281; called by muse, mutect2, varscan2
- SPINT1 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as rs371706199; called by muse, mutect2, varscan2
- SRCAP | c.7727C>T p.S2576L | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV52671160; called by muse, mutect2
- ST14 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1333246624, COSV53831383; called by muse, mutect2, varscan2
- ST8SIA4 | c.955G>T p.D319Y | Missense Mutation (SNP) | VAF 11/29 reads (38%) | PolyPhen possibly damaging (0.634); catalogued as COSV51508445; called by muse, mutect2, varscan2
- STAG2 | c.1717C>T p.Q573* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as COSV54351753; called by muse, mutect2, varscan2
- SYN3 | c.815G>A p.S272N | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1031636656; called by muse, mutect2, varscan2
- SYNJ1 | c.50G>A p.C17Y | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.506); catalogued as rs746182035; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TELO2 | c.1897C>T p.P633S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV51980115; called by muse, mutect2, varscan2
- TLE6 | c.1363C>G p.L455V (on ENST00000246112 / NM_001143986.2; = p.L332V on NM_024760.3) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV99857956; called by muse, mutect2
- TMEM106A | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as rs553206755, COSV59045780; called by muse, mutect2, varscan2
- TOR1AIP1 | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.895); catalogued as rs1458404277; called by muse, mutect2, varscan2
- TRPC4 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59005702; called by muse, mutect2, varscan2
- TTC3 | c.5800C>G p.P1934A | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs1380965866; called by muse, mutect2, varscan2
- TXNDC17 | c.304-7C>G | Splice Region (SNP) | VAF 17/40 reads (43%) | catalogued as rs1567600987, COSV51514183; called by muse, mutect2, varscan2
- TYRO3 | c.1238C>T p.S413F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.164); catalogued as rs1329746765; called by muse, mutect2, varscan2
- UQCR10 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as rs377432442, COSV57458710; called by muse, mutect2, varscan2
- USP19 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as rs1414836558; called by muse, mutect2, varscan2
- USP3 | c.1039C>T p.Q347* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as COSV51429720, COSV99165649; called by muse, mutect2, varscan2
- USP9X | c.3805G>A p.E1269K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV61067445; called by muse, mutect2, varscan2
- WAS | c.1361C>A p.S454* | Nonsense Mutation (SNP) | VAF 22/84 reads (26%) | catalogued as CM110517; called by muse, varscan2
- ZC3H12C | c.2111C>T p.P704L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs778003491, COSV53707192; called by muse, mutect2, varscan2
- ZC3H4 | c.3241C>T p.R1081W | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752786085, COSV99452845; called by muse, mutect2
- ZNF229 | c.1689G>C p.Q563H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1361781360, COSV52160815; called by muse, mutect2, varscan2
- ABCA2 | c.853G>C p.E285Q (on ENST00000614293; = p.E255Q on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ABCC3 | c.1196C>T p.S399L | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, varscan2
- ABHD3 | c.1226C>G p.S409C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.338); called by mutect2, varscan2
- ACACB | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 14/59 reads (24%) | called by muse, mutect2, varscan2
- ACSF2 | c.543C>G p.F181L | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ALMS1 | c.1024C>G p.L342V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- ARFGEF1 | c.1937C>G p.S646* | Nonsense Mutation (SNP) | VAF 6/69 reads (9%) | called by muse, mutect2
- ARL13A | c.439C>G p.L147V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASH1L | c.8683G>A p.E2895K (on ENST00000368346 / NM_001366177.2; = p.E2890K on NM_018489.3) | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ATAD5 | c.2724del p.K908Nfs*12 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel, varscan2
- ATF5 | c.667C>G p.L223V | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ATP13A5 | c.2539A>T p.M847L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- BLNK | c.149_152del p.R50Tfs*35 | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | called by mutect2, pindel, varscan2
- BNC1 | c.1146G>C p.K382N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C7orf31 | c.1157C>A p.A386D | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- C8B | c.467G>A p.R156K | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CACTIN | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | called by muse, varscan2
- CCNB3 | c.4000G>A p.E1334K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- CDC23 | c.1727C>T p.S576L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CFAP20DC | c.976G>C p.E326Q (on ENST00000482387 / NM_001351530.2; = p.E201Q on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- CHRNA1 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNOT10 | c.770G>A p.S257N | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- COL4A3 | c.539G>A p.G180E | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COPA | c.3256G>A p.E1086K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPSF3 | c.753G>C p.L251F | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CPSF3 | c.993G>A p.M331I | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CRISPLD1 | c.707G>C p.R236T | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.197); called by muse, mutect2
- CSF1 | c.299G>C p.R100T | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- CSPP1 | c.3133C>G p.H1045D (on ENST00000676605; = p.H1004D on NM_024790.6) | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CTRL | c.206G>C p.W69S | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CXXC1 | c.1574+7G>A | Splice Region (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- DOCK3 | c.4265C>T p.A1422V | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.881); called by mutect2, varscan2
- DOCK5 | c.4816A>T p.I1606F | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- DUOX1 | c.1216+3G>A | Splice Region (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- EDEM3 | c.40C>A p.P14T | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- EDIL3 | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EFCAB1 | c.518C>A p.A173D | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- ELFN2 | c.273C>G p.I91M | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ENPP6 | c.714C>G p.F238L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ERCC3 | c.582C>G p.I194M | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by mutect2, varscan2
- EVA1C | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- EXOC2 | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | called by muse, mutect2, varscan2
- EXOC5 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- FADS1 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAT3 | c.3643G>A p.E1215K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAT4 | c.10734G>C p.Q3578H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FGF8 | c.579G>A p.M193I (on ENST00000344255 / NM_033164.4; = p.M175I on NM_006119.6) | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- FKBPL | c.456G>T p.R152S | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- FN1 | c.562G>C p.D188H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FTSJ1 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FZD2 | c.1569C>G p.I523M | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- GJD2 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- GOLGB1 | c.8266G>A p.E2756K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GPD1L | c.871A>T p.K291* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- HECTD1 | c.6082C>T p.Q2028* | Nonsense Mutation (SNP) | VAF 12/101 reads (12%) | called by muse, mutect2, varscan2
- HGSNAT | c.644C>G p.S215C | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- HLA-DMB | c.187C>A p.P63T | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- HOXA1 | c.646A>C p.K216Q | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- HSPG2 | c.10219C>G p.Q3407E | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- HSPG2 | c.7256C>G p.S2419C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HUWE1 | c.3256C>T p.H1086Y | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- IQGAP1 | c.1084C>G p.Q362E | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- JCAD | c.1114C>G p.Q372E | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- KCNQ1 | c.1940C>T p.S647F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- KLF11 | c.415C>G p.L139V | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2D | c.9766G>A p.E3256K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- L3MBTL3 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LCE1B | c.275G>A p.S92N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- LMNB2 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- LRRC45 | c.918G>C p.Q306H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- MAOA | c.582C>G p.F194L | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- MAP1A | c.2941G>T p.E981* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- MAP2K5 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MAP3K21 | c.2011G>A p.D671N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.84); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MAPK8IP3 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- MON2 | c.872A>C p.Q291P | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- MUC4 | c.6985G>T p.A2329S | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.374); called by muse, varscan2
- MX1 | c.1499G>A p.R500K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NBR1 | c.2618C>G p.S873* | Nonsense Mutation (SNP) | VAF 16/78 reads (21%) | called by muse, mutect2, varscan2
- NHS | c.2459C>G p.S820C | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NHSL2 | c.1438G>A p.E480K (on ENST00000510661; = p.E846K on NM_001013627.2) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- NOS3 | c.397C>T p.Q133* | Nonsense Mutation (SNP) | VAF 13/21 reads (62%) | called by muse, mutect2, varscan2
- NPAS3 | c.1442C>G p.S481C (on ENST00000356141 / NM_001164749.2; = p.S449C on NM_022123.3) | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.319); called by muse, mutect2
- NPIPA1 | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 13/302 reads (4%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); called by muse, mutect2
- NR4A3 | c.1452C>T p.I484= | Splice Region (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2
- NRBP1 | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- NRBP1 | c.693G>C p.K231N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, varscan2
- NRBP1 | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.457); called by muse, varscan2
- NUP88 | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.958); called by muse, mutect2
- OAS2 | c.946C>G p.Q316E | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OLFML2B | c.1558G>C p.D520H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- PARP10 | c.1003C>G p.L335V | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- PAX9 | c.356C>G p.S119C | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PCDHB11 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PDE7A | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 94/108 reads (87%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLA2G6 | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 25/78 reads (32%) | called by muse, mutect2, varscan2
- POLA2 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- POMT1 | c.404G>C p.G135A | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- PPP1R3G | c.695A>G p.E232G | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- PPP1R3G | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PPP2R2B | c.1096G>C p.D366H (on ENST00000394409; = p.D432H on NM_181674.2) | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PRPS1 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- PRR14 | c.866C>A p.S289* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- PRUNE2 | c.3418G>A p.D1140N | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PTPA | c.999+3G>A | Splice Region (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- PWWP2B | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- RBM45 | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- REEP6 | c.225G>C p.E75D | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RELN | c.9149G>A p.G3050E | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- RFC2 | c.643G>A p.D215N (on ENST00000055077 / NM_181471.3; = p.D181N on NM_002914.4) | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RNASE2 | c.253C>G p.P85A | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- RNF40 | c.1185C>G p.F395L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RNF6 | c.1103C>G p.S368C | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- SAMD14 | c.419C>G p.S140C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2
- SCN7A | c.782G>A p.G261D | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SDHAF3 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SEMA3B | c.1681G>A p.D561N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- SEPHS1 | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SIGLEC15 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- SLCO1B1 | c.1384G>C p.D462H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- SNAPC2 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.114); called by muse, mutect2
- SNAPC2 | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2, varscan2
- SPEF2 | c.3605C>T p.S1202F | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.177); called by muse, mutect2
- SPTA1 | c.3095G>C p.R1032T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SRCAP | c.1879G>A p.D627N | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.19); called by muse, mutect2
- SRF | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- STRN3 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- STX18 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SUCO | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- SYNRG | c.2917C>G p.Q973E | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- SYT1 | c.270G>C p.K90N | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, varscan2
- TAL1 | c.715T>G p.L239V | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TBC1D9B | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- TMC7 | c.1406G>T p.C469F | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- TOMM20 | c.260A>T p.E87V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- TPM4 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- TRAP1 | c.1287G>C p.Q429H | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- TRIM46 | c.1834G>C p.E612Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- TRIM68 | c.1034_1036del p.N345del | In Frame Del (DEL) | VAF 7/38 reads (18%) | called by pindel, varscan2
- TUBGCP6 | c.5119G>T p.E1707* | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- TYW1B | c.1997C>G p.S666C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- UBN1 | c.2896C>G p.L966V | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- UBQLN4 | c.1264C>G p.Q422E | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- USP21 | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- USP31 | c.2609C>T p.S870F | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- USP38 | c.2090C>T p.S697F | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- UTS2B | c.64T>G p.F22V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VCL | c.786C>T p.D262= | Splice Region (SNP) | VAF 6/38 reads (16%) | called by mutect2, varscan2
- VSIG8 | c.109G>A p.G37S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WAS | c.1417G>A p.V473M | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, varscan2
- WDR18 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR62 | c.4057G>A p.A1353T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZFHX4 | c.4879G>T p.E1627* | Nonsense Mutation (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- ZFP36L1 | c.308dup p.Q104Afs*21 | Frame Shift Ins (INS) | VAF 40/67 reads (60%) | called by mutect2, pindel, varscan2
- ZMYND19 | c.606G>C p.Q202H | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- ZNF267 | c.1766C>G p.S589* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
- ZNF562 | c.592C>T p.L198F (on ENST00000453372 / NM_001130032.2; = p.L126F on NM_017656.4) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF850 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ABCA2 | c.3369G>A p.K1123= (on ENST00000614293; = p.K1093= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- ADGRB3 | c.4296G>A p.K1432= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV53236403; called by muse, mutect2, varscan2
- ADRM1 | c.630G>C p.R210= | Silent (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- ANKRD39 | c.447C>G p.L149= | Silent (SNP) | VAF 13/77 reads (17%) | called by muse, mutect2, varscan2
- AOAH | c.195G>C p.S65= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs747704933, COSV51736632; called by muse, mutect2, varscan2
- AP1M2 | c.753C>T p.R251= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs1281969203; called by muse, mutect2, varscan2
- ATAD3C | c.549G>A p.K183= | Silent (SNP) | VAF 31/48 reads (65%) | catalogued as COSV101112711; called by muse, mutect2, varscan2
- ATP2A1 | c.1146C>T p.F382= | Silent (SNP) | VAF 14/90 reads (16%) | called by muse, mutect2, varscan2
- BECN1 | c.168G>A p.E56= | Silent (SNP) | VAF 14/78 reads (18%) | called by mutect2, varscan2
- C2orf78 | c.1218C>G p.G406= | Silent (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- CACNA1H | c.753C>G p.L251= | Silent (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- CCDC22 | c.879C>T p.F293= | Silent (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- CERK | c.600C>T p.F200= | Silent (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- CHST5 | c.840C>G p.L280= | Silent (SNP) | VAF 17/61 reads (28%) | called by muse, mutect2, varscan2
- COG7 | c.93G>A p.G31= | Silent (SNP) | VAF 12/79 reads (15%) | called by muse, mutect2, varscan2
- COL7A1 | c.1773C>T p.V591= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as COSV60392125; called by muse, mutect2, varscan2
- COL9A2 | c.1377C>T p.S459= | Silent (SNP) | VAF 26/67 reads (39%) | called by muse, varscan2
- CRYBG2 | c.4839C>T p.I1613= | Silent (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- CYTH1 | c.1092G>A p.E364= | Silent (SNP) | VAF 13/64 reads (20%) | called by muse, mutect2, varscan2
- EFCAB13 | c.681G>A p.K227= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs1358165580, COSV100516620; called by muse, mutect2, varscan2
- EPHB6 | c.1542G>A p.Q514= | Silent (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
- EPPK1 | c.2541G>A p.R847= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV73260921; called by muse, mutect2, varscan2
- F7 | c.393C>T p.F131= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs1389405027; called by muse, mutect2, varscan2
- FAM133A | c.624G>A p.K208= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV59075438; called by muse, varscan2
- FAM47A | c.852G>A p.E284= | Silent (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- FCRL3 | c.24G>A p.L8= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV100943488; called by muse, mutect2, varscan2
- FKBPL | c.723G>A p.L241= | Silent (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
- GABRE | c.424C>T p.L142= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV64819837; called by muse, mutect2, varscan2
- GPR179 | c.894C>G p.L298= (on ENST00000621958; = p.L297= on NM_001004334.4) | Silent (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- HERC2 | c.13650G>A p.L4550= | Silent (SNP) | VAF 15/47 reads (32%) | called by muse, mutect2, varscan2
- HOOK3 | c.681C>T p.L227= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as COSV56881585; called by muse, mutect2, varscan2
- HPR | c.843C>T p.F281= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV57182579; called by muse, mutect2, varscan2
- IFI30 | c.165G>A p.K55= | Silent (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- IGLV7-43 | c.177G>A p.Q59= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs750211801; called by muse, mutect2, varscan2
- IL17RA | c.405G>A p.L135= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as rs1169409028; called by muse, mutect2, varscan2
- INSYN2A | c.441G>A p.A147= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs147680044; called by muse, mutect2, varscan2
- KBTBD12 | c.930C>T p.F310= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV59679871, COSV59682569; called by muse, mutect2, varscan2
- KHDC1 | c.78C>T p.F26= | Silent (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- KIAA1522 | c.477G>A p.R159= (on ENST00000373480 / NM_001198972.2; = p.R218= on NM_020888.3) | Silent (SNP) | VAF 23/45 reads (51%) | called by muse, mutect2, varscan2
- KIF27 | c.2685G>A p.P895= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs368455178; called by muse, mutect2, varscan2
- KLF14 | c.399C>T p.S133= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1554470985; called by muse, mutect2, varscan2
- KLF7 | c.672C>T p.N224= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs201005804, COSV58743383; called by muse, mutect2, varscan2
- LMTK3 | c.2718C>T p.D906= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs377699902; called by muse, mutect2, varscan2
- LRFN5 | c.81G>A p.Q27= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as COSV53263781; called by muse, mutect2, varscan2
- MMP17 | c.354G>A p.L118= | Silent (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- MOK | c.777C>G p.L259= | Silent (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- MRM2 | c.696C>T p.F232= | Silent (SNP) | VAF 11/45 reads (24%) | called by muse, mutect2
- MRM2 | c.513C>A p.I171= | Silent (SNP) | VAF 15/119 reads (13%) | called by muse, mutect2, varscan2
- MSI2 | c.75C>T p.I25= | Silent (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- MTR | c.1689C>T p.V563= | Silent (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- MYH8 | c.5154C>T p.L1718= | Silent (SNP) | VAF 13/70 reads (19%) | called by muse, mutect2, varscan2
- NABP2 | c.6G>A p.T2= | Silent (SNP) | VAF 12/47 reads (26%) | called by muse, mutect2, varscan2
- NINL | c.1062G>A p.V354= | Silent (SNP) | VAF 14/58 reads (24%) | called by muse, varscan2
- NLRP11 | c.2046C>G p.L682= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV64088788; called by mutect2, varscan2
- NOD1 | c.1740G>A p.K580= | Silent (SNP) | VAF 14/91 reads (15%) | called by muse, mutect2, varscan2
- NR1D1 | c.282C>T p.F94= | Silent (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- NXPE4 | c.1518C>T p.L506= (on ENST00000375478 / NM_001077639.2; = p.L222= on NM_017678.3) | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs1225561247, COSV100970296; called by muse, mutect2, varscan2
- OR10G9 | c.489C>T p.F163= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV66687002; called by muse, mutect2, varscan2
- OR9G1 | c.6G>A p.Q2= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs778402292, COSV56453750; called by muse, mutect2
- PET100 | c.213G>A p.Q71= | Silent (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- PKN3 | c.2034G>A p.K678= | Silent (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.2901C>G p.L967= (on ENST00000283426; = p.L1323= on NM_052909.5) | Silent (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- PNPLA8 | c.1158G>C p.L386= | Silent (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- PPHLN1 | c.1167G>A p.R389= | Silent (SNP) | VAF 23/106 reads (22%) | called by muse, varscan2
- PPP1R9B | c.1524C>T p.I508= | Silent (SNP) | VAF 11/73 reads (15%) | called by muse, mutect2, varscan2
- PTP4A3 | c.111G>A p.L37= | Silent (SNP) | VAF 8/124 reads (6%) | catalogued as rs1231943274; called by muse, mutect2
- PTPRS | c.1752G>C p.L584= | Silent (SNP) | VAF 20/73 reads (27%) | called by muse, varscan2
- RAPGEF4 | c.114G>A p.L38= | Silent (SNP) | VAF 6/26 reads (23%) | called by mutect2, varscan2
- RBM34 | c.81G>C p.G27= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs201983997; called by muse, mutect2
- RFC2 | c.885C>T p.I295= (on ENST00000055077 / NM_181471.3; = p.I261= on NM_002914.4) | Silent (SNP) | VAF 9/110 reads (8%) | called by muse, mutect2
- RTN4RL2 | c.405G>A p.S135= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as rs1353924881; called by muse, mutect2, varscan2
- SEC14L1 | c.1590C>T p.V530= | Silent (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2, varscan2
- SECTM1 | c.183C>T p.F61= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as rs1415214167; called by muse, mutect2, varscan2
- SH3PXD2B | c.1341C>T p.L447= | Silent (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- SHCBP1 | c.315C>T p.F105= | Silent (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2, varscan2
- SIPA1L2 | c.1368C>T p.S456= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs775181839, COSV99477592, COSV99478298; called by muse, mutect2, varscan2
- SLC15A2 | c.1935C>T p.L645= | Silent (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- SLC4A4 | c.2484C>T p.I828= (on ENST00000264485 / NM_001098484.3; = p.I784= on NM_003759.4) | Silent (SNP) | VAF 18/69 reads (26%) | called by muse, mutect2, varscan2
- SLCO3A1 | c.18G>C p.P6= | Silent (SNP) | VAF 14/44 reads (32%) | called by muse, varscan2
- ST7 | c.105C>T p.V35= | Silent (SNP) | VAF 51/69 reads (74%) | called by muse, mutect2, varscan2
- STRBP | c.1218C>T p.L406= | Silent (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- TFR2 | c.1923C>T p.L641= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as rs760383272; called by muse, mutect2, varscan2
- TUFM | c.57C>T p.L19= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs1351306896, COSV57948474; called by muse, mutect2, varscan2
- UBR3 | c.5364G>C p.L1788= | Silent (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- UCP3 | c.282C>T p.I94= | Silent (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- UNC80 | c.8091G>A p.V2697= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs776047891; called by mutect2, varscan2
- USE1 | c.12G>A p.S4= | Silent (SNP) | VAF 40/66 reads (61%) | catalogued as rs1230385312; called by muse, mutect2, varscan2
- VMP1 | c.588C>T p.I196= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs757075911; called by muse, mutect2, varscan2
- WIZ | c.4422C>T p.F1474= (on ENST00000673675 / NM_001371589.1; = p.F379= on NM_021241.3) | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV99653970; called by muse, mutect2, varscan2
- ZNF410 | c.1029C>G p.V343= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs1013117845; called by muse, mutect2, varscan2
- ZSWIM5 | c.3144C>T p.L1048= | Silent (SNP) | VAF 31/46 reads (67%) | catalogued as rs1353983972, COSV55799396, COSV55800202; called by muse, mutect2, varscan2
- ABCA2 | c.7365+166G>A | Intron (SNP) | VAF 8/22 reads (36%) | catalogued as rs748668007; called by muse, mutect2, varscan2
- AIM2 | c.*4A>T | 3'UTR (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- ALOXE3 | chr17:8118734 G>A | 5'Flank (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2, varscan2
- AP1G1 | c.1088+372C>G | Intron (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- AQP12A | c.-41C>T | 5'UTR (SNP) | VAF 5/30 reads (17%) | catalogued as rs1342817226; called by muse, mutect2, varscan2
- CACNG4 | c.*533C>T | 3'UTR (SNP) | VAF 8/71 reads (11%) | catalogued as rs750278676; called by mutect2, varscan2
- CCDC120 | chrX:49068627 C>T | 3'Flank (SNP) | VAF 5/22 reads (23%) | called by muse, varscan2
- CD1C | c.*45C>T | 3'UTR (SNP) | VAF 13/43 reads (30%) | catalogued as rs1160318058; called by muse, mutect2, varscan2
- CFAP300 | c.-1G>C | 5'UTR (SNP) | VAF 14/50 reads (28%) | catalogued as rs948850801, COSV101462467; called by muse, mutect2
- COQ5 | c.203-1561G>A | Intron (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2, varscan2
- CROT | c.116-1693G>A | Intron (SNP) | VAF 8/190 reads (4%) | called by muse, mutect2
- DDX19A | c.293+641C>G | Intron (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- DLG5 | c.373+1145G>A | Intron (SNP) | VAF 16/42 reads (38%) | catalogued as rs1474539990; called by muse, mutect2, varscan2
- DTX3 | c.-9C>T | 5'UTR (SNP) | VAF 11/51 reads (22%) | catalogued as COSV99677938; called by muse, mutect2, varscan2
- DYNLRB1 | c.3+291G>C | Intron (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2, varscan2
- EFHB | chr3:19936243 G>A | 5'Flank (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- EPB41L4A | c.*2C>G | 3'UTR (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- FMR1 | c.*1014G>A | 3'UTR (SNP) | VAF 6/30 reads (20%) | catalogued as rs1557183135; called by muse, varscan2
- FRMD8P1 | n.634G>A | RNA (SNP) | VAF 13/71 reads (18%) | called by muse, mutect2, varscan2
- GCFC2 | c.1226+19G>T | Intron (SNP) | VAF 8/42 reads (19%) | catalogued as rs1301650804; called by muse, mutect2, varscan2
- H2BC7 | c.-1C>G | 5'UTR (SNP) | VAF 5/20 reads (25%) | catalogued as rs377404972; called by muse, mutect2
- HAGHL | c.288+39C>G | Intron (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- HIRA | c.-27C>T | 5'UTR (SNP) | VAF 9/49 reads (18%) | called by muse, varscan2
- HSP90B3P | n.365A>G | RNA (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- IGFBP3 | c.-15C>T | 5'UTR (SNP) | VAF 14/93 reads (15%) | catalogued as rs1166718927; called by muse, mutect2, varscan2
- IHO1 | chr3:49260874 C>G | 3'Flank (SNP) | VAF 16/58 reads (28%) | called by muse, mutect2, varscan2
- INTS14 | c.-63+16G>C | Intron (SNP) | VAF 12/50 reads (24%) | catalogued as COSV57526024; called by muse, mutect2
- IRGM | c.*7C>A | 3'UTR (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- LIMK2 | c.1773-1301C>T | Intron (SNP) | VAF 19/97 reads (20%) | catalogued as rs1242175543, COSV99313926; called by muse, mutect2, varscan2
- LRRC37B | c.2124-4170C>T | Intron (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- NPEPPSP1 | n.91C>T | RNA (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- PLA2G6 | c.426-26C>T | Intron (SNP) | VAF 19/66 reads (29%) | called by muse, mutect2, varscan2
- PLCD3 | c.1712-41C>T | Intron (SNP) | VAF 12/30 reads (40%) | catalogued as rs776732308; called by muse, mutect2
- PLEKHA7 | c.-4G>A | 5'UTR (SNP) | VAF 6/37 reads (16%) | called by muse, mutect2, varscan2
- POLR2C | c.387+58C>G | Intron (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- RPAIN | c.631-895C>A | Intron (SNP) | VAF 18/32 reads (56%) | called by muse, mutect2, varscan2
- RRP7A | c.*3874G>A | 3'UTR (SNP) | VAF 14/41 reads (34%) | catalogued as rs766236553; called by muse, mutect2, varscan2
- SLC29A1 | chr6:44223612 C>G | 5'Flank (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- SMARCB1 | c.363-2179G>A | Intron (SNP) | VAF 7/33 reads (21%) | catalogued as rs985462369; called by muse, mutect2, varscan2
- SREBF1 | c.2736-18C>T | Intron (SNP) | VAF 10/42 reads (24%) | called by muse, varscan2
- TMEM135 | c.-22C>T | 5'UTR (SNP) | VAF 22/90 reads (24%) | catalogued as rs1446758222; called by muse, mutect2, varscan2
- TUFM | c.923-46C>T | Intron (SNP) | VAF 24/109 reads (22%) | catalogued as rs772287808; called by muse, mutect2, varscan2
- UHRF1 | c.-10-1282C>T | Intron (SNP) | VAF 12/50 reads (24%) | catalogued as rs1387710738; called by muse, mutect2, varscan2
- USE1 | c.394+137G>A | Intron (SNP) | VAF 32/70 reads (46%) | called by muse, varscan2
- VPS11 | c.-163C>G | 5'UTR (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- ZNF274 | c.-15G>C | 5'UTR (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
- ZNF44 | c.147+1986G>C | Intron (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
